Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CL, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CL-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

100-0-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS C73.9

lw 4/18/11

Specimen(s) Received

1. Soft-Tissue: left thyroid lobe and isthmus

Diagnosis

Multifocal papillary carcinoma, dominant 2.5 cm: Thyroid, left hemithyroidectomy specimen.

Synoptic Data

Procedure:	Left hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Left lobe:
	5.3 cm
	2.8 cm
	1.8 cm
	Isthmus +/- pyramidal lobe:
	2.2 cm
	1.3 cm
	0.9 cm
Specimen Weight:	15.3 g
Tumor Focality:	Multifocal, ipsilateral

----- DOMINANT TUMOR -----

Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 2.5cm
	Additional dimension: 2.3 cm
	Additional dimension: 1.8 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified

[page 2 of 2]
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 0.1 cm
Histologic Type:	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Ancillary Studies:	Type: Immunohistochemistry Results: CK-19 positive, HBME-1 focally positive, Galectin negative

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

verified by:

Electronically

Gross Description

The specimen labeled with the patient's name and as "Soft Tissue: Left thyroid lobe and isthmus" consists of a left hemithyroidectomy specimen that is not oriented and weighs 15.3 g. The lobe measures 5.3 cm SI x 2.8 cm ML x 1.8 cm AP and the isthmus measures 2.2 SI x 1.3 cm ML x 0.9 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The lower pole of the lobe contains a well delineated nodule that measures 2.5 cm SI x 2.3 cm ML x 1.8 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior
1K-M isthmus

Source: NCI Genomic Data Commons file df23b2cd-6dcb-4c38-b842-3a5c2e1f3481 (TCGA-EM-A2CL.2C563AAE-210A-40FB-9FB3-23FCD79E9D19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).